Somatic mutation profile of tumor specimen MMRF_2652_1_BM_CD138pos (aliquot MMRF_2652_1_BM_CD138pos_T1_KHS5U_L13772) from MMRF case MMRF_2652, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.5 years (23,921 days).
Specimen MMRF_2652_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b472acc-c485-4956-88c1-c3f3c0b27794.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2652_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2652_1_PB_WBC_C3_KHS5U_L13773; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c10e174-034c-4669-a1c5-df938bbe3f3e

The open-access MAF lists 118 somatic variants for this specimen: 31 protein-altering or splice-affecting, 16 silent, 71 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 36, Missense Mutation 26, Silent 16, Intron 14, 5'UTR 8, 5'Flank 7, 3'Flank 3, Nonsense Mutation 3, RNA 3, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 54/381 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN2 | c.2506C>T p.R836W | Missense Mutation (SNP) | VAF 24/381 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs727502887, COSV63974742; called by muse, mutect2
- AQR | c.4207G>T p.E1403* | Nonsense Mutation (SNP) | VAF 152/326 reads (47%) | catalogued as COSV99334026; called by muse, mutect2, varscan2
- CDX1 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV51568361; called by muse, mutect2, varscan2
- COA8 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 94/161 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV54572942; called by muse, mutect2
- FASN | c.2921G>A p.S974N | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1460984377; called by muse, mutect2, varscan2
- FZD10 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 85/94 reads (90%) | catalogued as COSV57472758; called by muse, mutect2, varscan2
- IGLV3-21 | c.252C>G p.N84K | Missense Mutation (SNP) | VAF 76/82 reads (93%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs540297754; called by muse, varscan2
- JPH1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 155/309 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs756673688; called by muse, mutect2, varscan2
- KDM3A | c.1005A>G p.Q335= | Splice Region (SNP) | VAF 15/183 reads (8%) | catalogued as rs535868641; called by muse, mutect2
- LMNB2 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 130/266 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.85); catalogued as rs769178156, COSV100322334; called by muse, mutect2, varscan2
- OR8B12 | c.180C>A p.F60L | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); catalogued as COSV60912583; called by muse, mutect2
- PTPRS | c.1945G>A p.G649R | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs767837276; called by muse, mutect2, varscan2
- TENM2 | c.5779G>A p.A1927T (on ENST00000518659 / NM_001122679.2; = p.A1688T on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.604); catalogued as rs746005117; called by muse, mutect2, varscan2
- WDR64 | c.3022G>A p.V1008I | Missense Mutation (SNP) | VAF 170/273 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as rs777870685; called by muse, mutect2, varscan2
- C9 | c.317A>C p.Q106P | Missense Mutation (SNP) | VAF 103/227 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- CCDC171 | c.974C>A p.A325D | Missense Mutation (SNP) | VAF 120/265 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CFAP70 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 90/230 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- FREM1 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- HIBADH | c.363-1G>A p.X121_splice | Splice Site (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- MAP9 | c.1333A>T p.R445* | Nonsense Mutation (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- NCOR1 | c.2114C>T p.T705I | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- OXR1 | c.2434G>A p.D812N (on ENST00000442977 / NM_001198532.1; = p.D784N on NM_018002.3) | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLS3 | c.1641G>C p.K547N | Missense Mutation (SNP) | VAF 73/78 reads (94%) | SIFT tolerated (0.08); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- POU5F1B | c.639C>A p.N213K | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- PUS10 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 76/156 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- SEL1L | c.2108T>G p.V703G | Missense Mutation (SNP) | VAF 99/107 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SHANK2 | c.2801C>T p.P934L | Missense Mutation (SNP) | VAF 43/336 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRAV14DV4 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); called by muse, mutect2, varscan2
- WDR37 | c.1315G>A p.G439R | Missense Mutation (SNP) | VAF 35/229 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.246C>T p.N82= | Silent (SNP) | VAF 67/155 reads (43%) | called by muse, mutect2, varscan2
- COL4A2 | c.2856C>T p.F952= | Silent (SNP) | VAF 77/80 reads (96%) | catalogued as rs747574881, COSV64625998; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYP4F3 | c.591C>T p.L197= | Silent (SNP) | VAF 108/219 reads (49%) | called by muse, mutect2, varscan2
- DUOX2 | c.3660G>A p.L1220= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as rs757964910; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DVL1 | c.618C>T p.S206= | Silent (SNP) | VAF 83/95 reads (87%) | catalogued as rs1304620785; called by muse, mutect2, varscan2
- HIVEP2 | c.3027C>A p.V1009= | Silent (SNP) | VAF 97/230 reads (42%) | called by muse, mutect2, varscan2
- KCP | c.573C>T p.I191= | Silent (SNP) | VAF 67/136 reads (49%) | called by muse, mutect2, varscan2
- KLHDC9 | c.174G>A p.T58= | Silent (SNP) | VAF 182/530 reads (34%) | catalogued as rs1196741886; called by muse, mutect2, varscan2
- MUC16 | c.17379C>A p.I5793= | Silent (SNP) | VAF 113/228 reads (50%) | catalogued as rs763264937, COSV67489580; called by muse, mutect2, varscan2
- SCN11A | c.306C>A p.R102= | Silent (SNP) | VAF 157/344 reads (46%) | called by muse, mutect2, varscan2
- SLC4A10 | c.1866G>A p.R622= (on ENST00000446997 / NM_001354461.2; = p.R592= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 18/324 reads (6%) | catalogued as rs1482342619; called by muse, mutect2
- TRIP11 | c.1449C>A p.L483= | Silent (SNP) | VAF 35/40 reads (88%) | called by muse, mutect2, varscan2
- TSPAN13 | c.18C>T p.F6= | Silent (SNP) | VAF 183/402 reads (46%) | catalogued as COSV100018157; called by muse, mutect2, varscan2
- WDR27 | c.1512C>T p.I504= | Silent (SNP) | VAF 79/170 reads (46%) | called by muse, mutect2, varscan2
- ZER1 | c.987C>T p.L329= | Silent (SNP) | VAF 153/283 reads (54%) | catalogued as rs369344756; called by muse, mutect2, varscan2
- ZSCAN29 | c.2052G>T p.G684= | Silent (SNP) | VAF 133/271 reads (49%) | catalogued as COSV101212172; called by muse, mutect2, varscan2
- ABL2 | c.*5385A>G | 3'UTR (SNP) | VAF 45/65 reads (69%) | catalogued as rs1458588594; called by muse, mutect2, varscan2
- ADRA1A | c.*208G>T | 3'UTR (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- ARHGEF34P | n.1276T>C | RNA (SNP) | VAF 22/129 reads (17%) | called by muse, mutect2, varscan2
- ARMC8 | c.*1600G>A | 3'UTR (SNP) | VAF 22/276 reads (8%) | called by muse, mutect2
- BMP3 | c.*1831C>G | 3'UTR (SNP) | VAF 54/104 reads (52%) | called by muse, varscan2
- BPI | c.*123G>A | 3'UTR (SNP) | VAF 14/88 reads (16%) | catalogued as rs570718035; called by muse, mutect2, varscan2
- C1QTNF7 | c.*2796G>A | 3'UTR (SNP) | VAF 58/125 reads (46%) | called by muse, varscan2
- CACNA1E | c.-16C>T | 5'UTR (SNP) | VAF 61/207 reads (29%) | called by muse, mutect2, varscan2
- CACNA1E | c.*889A>G | 3'UTR (SNP) | VAF 103/162 reads (64%) | called by muse, mutect2, varscan2
- CCDC80 | c.*508C>G | 3'UTR (SNP) | VAF 19/48 reads (40%) | called by muse, mutect2, varscan2
- CENPP | c.*1461A>G | 3'UTR (SNP) | VAF 54/106 reads (51%) | called by muse, mutect2, varscan2
- CEP112 | c.2395-92G>C | Intron (SNP) | VAF 77/146 reads (53%) | called by muse, mutect2, varscan2
- CEP44 | c.*738G>A | 3'UTR (SNP) | VAF 49/51 reads (96%) | catalogued as rs1044426790; called by muse, mutect2, varscan2
- CHRM2 | chr7:137016725 ins A | 3'Flank (INS) | VAF 42/100 reads (42%) | called by mutect2, varscan2
- CLIP1 | c.3966+1462C>G | Intron (SNP) | VAF 43/48 reads (90%) | called by muse, mutect2, varscan2
- CPTP | chr1:1324778 G>C | 5'Flank (SNP) | VAF 11/11 reads (100%) | called by muse, mutect2, varscan2
- CSRNP3 | c.*3601G>A | 3'UTR (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- CTTN | c.*1066C>T | 3'UTR (SNP) | VAF 32/61 reads (52%) | catalogued as rs1252623688; called by muse, mutect2, varscan2
- CYCS | c.*2908C>T | 3'UTR (SNP) | VAF 43/73 reads (59%) | called by muse, mutect2, varscan2
- DAGLA | c.*1648C>T | 3'UTR (SNP) | VAF 231/469 reads (49%) | catalogued as rs372760246; called by muse, mutect2, varscan2
- EIF3A | c.*1975C>T | 3'UTR (SNP) | VAF 26/242 reads (11%) | called by muse, mutect2, varscan2
- EIF4E3 | c.*4794G>T | 3'UTR (SNP) | VAF 33/100 reads (33%) | called by muse, varscan2
- EIF5A2 | c.*3537C>G | 3'UTR (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2, varscan2
- ESRRA | c.-189T>A | 5'UTR (SNP) | VAF 13/110 reads (12%) | called by muse, mutect2, varscan2
- FAF2 | c.*1756G>A | 3'UTR (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- FBXL17 | c.*1835G>A | 3'UTR (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- GMEB1 | chr1:28715656 C>T | 3'Flank (SNP) | VAF 7/27 reads (26%) | catalogued as rs983753189; called by muse, mutect2, varscan2
- GPR156 | c.*403G>C | 3'UTR (SNP) | VAF 7/164 reads (4%) | called by muse, mutect2
- HEBP2 | chr6:138403463 C>T | 5'Flank (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- HTR1A | c.-119C>G | 5'UTR (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- IL6R | c.*142C>G | 3'UTR (SNP) | VAF 68/207 reads (33%) | called by muse, mutect2, varscan2
- ING5 | c.*1812G>A | 3'UTR (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- ITGBL1 | c.-91C>T | 5'UTR (SNP) | VAF 76/84 reads (90%) | called by muse, mutect2, varscan2
- ITPKB | chr1:226737570 C>T | 5'Flank (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- IYD | c.*7424C>T | 3'UTR (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2
- LTB | c.209-88G>A | Intron (SNP) | VAF 56/111 reads (50%) | called by muse, mutect2, varscan2
- MIR4487 | n.19C>T | RNA (SNP) | VAF 8/32 reads (25%) | called by muse, varscan2
- MIR5195 | chr14:106851231 C>G | 5'Flank (SNP) | VAF 190/211 reads (90%) | catalogued as rs560502100; called by muse, mutect2, varscan2
- MIR539 | n.47G>A | RNA (SNP) | VAF 80/277 reads (29%) | called by muse, mutect2, varscan2
- NEMP2 | c.*1058G>A | 3'UTR (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
- NIM1K | c.-97C>A | 5'UTR (SNP) | VAF 11/281 reads (4%) | catalogued as COSV100389997; called by muse, mutect2
- NIPAL2 | c.*912T>A | 3'UTR (SNP) | VAF 30/68 reads (44%) | catalogued as rs1198540167; called by muse, mutect2, varscan2
- PARK7 | c.*13C>T | 3'UTR (SNP) | VAF 14/49 reads (29%) | catalogued as rs752679225, COSV100096518; called by muse, mutect2, varscan2
- PDE1C | c.1892-8690C>A | Intron (SNP) | VAF 113/253 reads (45%) | called by muse, mutect2, varscan2
- PDS5A | c.138+22G>A | Intron (SNP) | VAF 112/218 reads (51%) | catalogued as rs369964720; called by muse, mutect2, varscan2
- PIM1 | c.-266A>T | 5'UTR (SNP) | VAF 37/58 reads (64%) | called by muse, mutect2, varscan2
- PIP4K2A | c.678+101G>A | Intron (SNP) | VAF 92/246 reads (37%) | called by muse, varscan2
- PLPP1 | c.-140C>T | 5'UTR (SNP) | VAF 21/54 reads (39%) | catalogued as rs1323696711; called by muse, mutect2, varscan2
- PTEN | c.*4915A>C | 3'UTR (SNP) | VAF 80/170 reads (47%) | called by mutect2, varscan2
- PXN | c.831+1599C>T | Intron (SNP) | VAF 48/53 reads (91%) | catalogued as rs1226940998; called by muse, mutect2, varscan2
- PYROXD2 | c.147+33G>A | Intron (SNP) | VAF 62/319 reads (19%) | called by muse, mutect2, varscan2
- RTEL1 | c.*43C>T | 3'UTR (SNP) | VAF 45/101 reads (45%) | called by muse, mutect2, varscan2
- SEC61A2 | c.463-1959G>A | Intron (SNP) | VAF 28/320 reads (9%) | catalogued as rs749521771; called by muse, mutect2
- SEMA3D | c.*3467A>G | 3'UTR (SNP) | VAF 6/42 reads (14%) | called by mutect2, varscan2
- SLC5A1 | c.*1102G>C | 3'UTR (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- SMAD2 | c.*4226T>G | 3'UTR (SNP) | VAF 16/51 reads (31%) | called by muse, mutect2, varscan2
- SMIM15 | c.*694G>A | 3'UTR (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- SRPK1 | chr6:35921112 C>T | 5'Flank (SNP) | VAF 105/190 reads (55%) | called by muse, mutect2, varscan2
- SSR3 | c.*2060G>A | 3'UTR (SNP) | VAF 18/166 reads (11%) | catalogued as rs543172022; called by muse, mutect2, varscan2
- STAG3 | c.1770+37A>C | Intron (SNP) | VAF 63/157 reads (40%) | called by muse, mutect2, varscan2
- TAGLN | c.-12-1244C>T | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- TBCC | c.*306C>T | 3'UTR (SNP) | VAF 12/25 reads (48%) | called by muse, mutect2, varscan2
- TMF1 | chr3:69052334 G>T | 5'Flank (SNP) | VAF 141/306 reads (46%) | called by muse, mutect2, varscan2
- TRIM37 | c.*129G>A | 3'UTR (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- TRIM73 | chr7:75414419 G>A | 3'Flank (SNP) | VAF 94/271 reads (35%) | called by muse, mutect2, varscan2
- U2SURP | c.-31T>C | 5'UTR (SNP) | VAF 60/155 reads (39%) | catalogued as rs573249900, COSV101204360; called by muse, varscan2
- ZKSCAN8 | chr6:28137015 G>A | 5'Flank (SNP) | VAF 32/322 reads (10%) | called by muse, mutect2
- ZNF286A | c.127-2060del | Intron (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- ZNF512B | c.*507C>T | 3'UTR (SNP) | VAF 31/239 reads (13%) | called by muse, mutect2, varscan2
- ZNF609 | c.747+383A>G | Intron (SNP) | VAF 117/228 reads (51%) | called by muse, mutect2, varscan2
- ZZEF1 | c.7212+24C>T | Intron (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
